Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7596, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7596-01A (Primary Tumor).

Reg#: [REDACTED] Name: [REDACTED] DOB: [REDACTED] Sex: [REDACTED] Age: [REDACTED] User Name: [REDACTED]

ACCN Number	Order Test Code	Order Test Name	Last Updated
ACCN: [REDACTED] Collected: [REDACTED]	SPF	SP FINAL REPORT	Updated [REDACTED]
SP FINAL REPORT		Source:	
HISTORY: History of right neck mass x three months with sore throat. CT imaging right base of tongue and right level II neck mass. Operative Procedure: DL, esophagoscopy and biopsy. Please test for HPV, P-16, EGFR. GROSS: 1. "Right tonsil" Received in formalin in a small container is a 2.5 x 1.7 x 0.3 cm aggregate of soft rubbery gray-white hemorrhagic tissue. (ns) 2. "Core biopsy right level II lymph node" Received in formalin in a small container is a 0.3 cm gray-tan bit. (ns) [REDACTED] [REDACTED] MICROSCOPIC DIAGNOSIS: 1. Right tonsil, biopsy: Invasive non-keratinizing squamous cell carcinoma, moderately-poorly differentiated. 2. Level II lymph node, core biopsy: Scar tissue with a microscopic focus of metastatic squamous cell carcinoma. [REDACTED] I, [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case. [REDACTED]			

[Close](#)

Source: NCI Genomic Data Commons file d1a1a817-c540-48c3-ad46-d181fd157ed0 (TCGA-DQ-7596.8F31D45F-2FEF-4AE5-8A34-EA8E7750AB9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).